Somatic mutation profile of tumor specimen TCGA-2G-AAG0-01A (aliquot TCGA-2G-AAG0-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAG0, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 23.8 years (8,687 days).
Specimen TCGA-2G-AAG0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a68a9be5-3d1e-4b6f-9469-bd6aedcdf8eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAG0-10A (Blood Derived Normal), aliquot TCGA-2G-AAG0-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3346b707-1cad-4c72-a4b4-711b5d2e588e

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 2, 5'UTR 1, Nonsense Mutation 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.248C>A p.P83Q | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs750568629; called by muse, mutect2, varscan2
- CAPNS2 | c.611T>A p.M204K | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV100045065; called by muse, mutect2, varscan2
- DGKI | c.1587C>A p.N529K | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55974708; called by muse, mutect2
- IRF4 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101110959, COSV66705703; called by muse, mutect2, varscan2
- OR1L8 | c.272_274del p.K91del | In Frame Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs1321243034; called by pindel, varscan2
- PARP12 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99694190; called by muse, mutect2, varscan2
- RPL26 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV53447242; called by muse, varscan2
- SUCLG2 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56209953; called by muse, mutect2, varscan2
- THRA | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV52841256; called by muse, mutect2, varscan2
- ZNF75A | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV73039636; called by muse, mutect2, varscan2
- CNTNAP4 | c.2368T>C p.S790P | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPBP1L1 | c.11A>C p.H4P | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GULP1 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NUMA1 | c.6166C>T p.P2056S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLPPR5 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- RTKN2 | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2
- SCN9A | c.4081G>C p.A1361P (on ENST00000303354; = p.A1350P on NM_002977.3) | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- SLC23A1 | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- BSX | c.636C>G p.T212= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs781680432, COSV100545269; called by muse, mutect2
- MAP1S | c.2169C>A p.G723= | Silent (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2
- MATN1 | c.-31C>T | 5'UTR (SNP) | VAF 16/83 reads (19%) | catalogued as rs771549900; called by muse, varscan2
- MYO15A | c.8340+12T>C | Intron (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
